Gene-level copy-number profile of tumor specimen TCGA-73-A9RS-01A from TCGA case TCGA-73-A9RS, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.5 years (15,162 days).
Specimen TCGA-73-A9RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3d4afc95-7df5-44f4-a947-7ec42516b33b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-73-A9RS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a5a8ffc0-2bbe-4b72-bcea-7dedc710a1e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,584; copy number 2: 25,954; copy number 3: 18,373; copy number 4: 11,406; copy number 5: 1,253; copy number 6: 191; copy number 7: 18; copy number 8: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-73-A9RS-01A-11D-A40Z-01): tumor purity 0.61, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:31,475,398–31,870,789, 3 genes (within-gene range 0–2): OTUD7A, DEPDC1P1, AC026951.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,497 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–153,923,360, 457 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:4,945,277–16,204,226, 174 genes, copy number 6–7 (broad region; genes not listed).
- chr2:16,227,027–16,228,194, 1 gene, copy number 7: AC010745.3.
- chr2:17,663,812–17,817,798, 3 genes, copy number 6: SMC6, GEN1, MSGN1.
- chr2:18,784,807–20,106,829, 18 genes, copy number 6 (within-gene range 3–6): AC106053.1, AC130814.1, LINC01376, MIR4757, OSR1, AC010096.1, LINC01808, AC019055.1, CISD1P1, LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1.
- chr2:20,999,313–21,970,959, 13 genes, copy number 6: AC115619.1, APOB, AC010872.1, AC010872.2, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P.
- chr2:22,508,129–28,338,901, 147 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr2:138,278,574–156,342,348, 194 genes, copy number 5 (broad region; genes not listed).
- chr2:182,140,036–182,523,192, 3 genes, copy number 5: PDE1A, AC012500.1, RN7SL267P.
- chr4:19,098,199–23,904,089, 35 genes, copy number 5: AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1, AC092440.1, RFPL4AP3, AC093607.1, ERVH-1, PPARGC1A, AC092834.1.
- chr7:51,382,284–64,220,508, 265 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:101,815,904–102,283,958, 1 gene, copy number 5 (within-gene range 3–5): CUX1.
- chr7:101,960,116–103,344,830, 57 genes, copy number 5 (within-gene range 3–5): AC005072.1, AC005086.2, AC005086.5, AC005086.4, AC005086.3, AC005086.1, AC005088.1, SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O, AC073517.1, ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2, RASA4DP, AC105052.5, FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2.
- chr11:77,322,017–80,762,826, 52 genes, copy number 5 (within-gene range 4–5): PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720.
- chr11:81,821,272–85,627,922, 44 genes, copy number 5 (within-gene range 4–5): MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3.
- chr14:36,320,753–36,656,163, 1 gene, copy number 5 (within-gene range 4–5): AL132857.1.
- chr14:36,473,207–38,371,338, 32 genes, copy number 5: SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1.

Autosomal genes at a single copy (total copy number 1): 909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
